MMRF case MMRF_1436 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/34eaf0d5-6b79-435f-8f74-276ce012099a

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 64 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 64.4 years (23,530 days); ISS stage: I; Days to last known disease status: 1,333 days (3.6 years); Days to last follow up: 1,333 days (3.6 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 323 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 323 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -4 (ECOG 0): M Protein 2.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 21.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 7.61 mg/dL; Immunoglobulin G 6.49 g/L; Immunoglobulin A 38.8 g/L; Immunoglobulin M 0.15 g/L; Beta 2 Microglobulin 1.9 µg/mL; Hemoglobin 7.81 mmol/L; Leukocytes 3 ×10⁹/L; Absolute Neutrophil 1.4 ×10⁹/L; Platelets 231 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.35 mmol/L; Albumin 39 g/L; Total Protein 9.4 g/dL; Glucose 6 mmol/L.
- Day 87: Immunoglobulin G 5.43 g/L; Immunoglobulin A 8.49 g/L; Immunoglobulin M 0.2 g/L; Hemoglobin 7.75 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 1.4 ×10⁹/L; Platelets 272 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.45 mmol/L; Albumin 40 g/L; Total Protein 6.9 g/dL; Glucose 5.23 mmol/L.
- Day 177: Immunoglobulin A 4.19 g/L; Hemoglobin 8.87 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 197 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.43 mmol/L; Albumin 42 g/L; Total Protein 6.9 g/dL; Glucose 4.9 mmol/L.
- Day 280 (ECOG 0): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.852 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.979 mg/dL; Immunoglobulin G 6.96 g/L; Immunoglobulin A 3.86 g/L; Immunoglobulin M 0.07 g/L; Hemoglobin 8.43 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 217 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.4 mmol/L; Albumin 43 g/L; Total Protein 6.7 g/dL; Glucose 6.22 mmol/L.
- Day 350 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.05 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.04 mg/dL; Immunoglobulin G 8.41 g/L; Immunoglobulin A 3.53 g/L; Immunoglobulin M 0.19 g/L; Hemoglobin 8.87 mmol/L; Leukocytes 7.7 ×10⁹/L; Absolute Neutrophil 7.4 ×10⁹/L; Platelets 210 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.6 mmol/L; Albumin 44 g/L; Total Protein 7.3 g/dL; Glucose 11.2 mmol/L.
- Day 434 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.38 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.04 mg/dL; Immunoglobulin G 7.19 g/L; Immunoglobulin A 2.86 g/L; Immunoglobulin M 0.15 g/L; Hemoglobin 8.68 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 5.3 ×10⁹/L; Platelets 202 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.58 mmol/L; Albumin 44 g/L; Total Protein 6.9 g/dL; Glucose 10.2 mmol/L.
- Day 540 (ECOG 0): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.28 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.93 mg/dL; Immunoglobulin G 6.38 g/L; Immunoglobulin A 2.42 g/L; Immunoglobulin M 0.18 g/L; Hemoglobin 8.31 mmol/L; Leukocytes 8.5 ×10⁹/L; Absolute Neutrophil 5.7 ×10⁹/L; Platelets 185 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.38 mmol/L; Albumin 42 g/L; Total Protein 6.6 g/dL; Glucose 4.68 mmol/L.
- Day 627 (ECOG 0): Immunoglobulin G 6.47 g/L; Immunoglobulin A 1.98 g/L; Immunoglobulin M 0.2 g/L; Hemoglobin 8.56 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 233 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.25 mmol/L; Albumin 38 g/L; Total Protein 6.3 g/dL; Glucose 4.18 mmol/L.
- Day 731 (ECOG 0): Immunoglobulin G 6.45 g/L; Immunoglobulin A 1.66 g/L; Hemoglobin 8.12 mmol/L; Leukocytes 3.4 ×10⁹/L; Absolute Neutrophil 1.4 ×10⁹/L; Platelets 219 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.38 mmol/L; Albumin 40 g/L; Total Protein 6 g/dL; Glucose 4.95 mmol/L.
- Day 806 (ECOG 0): Immunoglobulin G 6.17 g/L; Immunoglobulin A 1.59 g/L; Immunoglobulin M 0.2 g/L; Hemoglobin 8.18 mmol/L; Leukocytes 7.2 ×10⁹/L; Absolute Neutrophil 4.9 ×10⁹/L; Platelets 186 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.43 mmol/L; Albumin 40 g/L; Total Protein 6.3 g/dL; Glucose 5.78 mmol/L.
- Day 889 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.41 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.33 mg/dL; Immunoglobulin G 7.1 g/L; Immunoglobulin A 1.82 g/L; Immunoglobulin M 0.24 g/L; Hemoglobin 8.99 mmol/L; Leukocytes 5.4 ×10⁹/L; Absolute Neutrophil 4.7 ×10⁹/L; Platelets 211 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.5 mmol/L; Albumin 44 g/L; Total Protein 6.6 g/dL; Glucose 7.15 mmol/L.
- Day 976 (ECOG 0): Immunoglobulin G 6.4 g/L; Immunoglobulin A 1.44 g/L; Immunoglobulin M 0.22 g/L; Hemoglobin 8.49 mmol/L; Leukocytes 4.5 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 177 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.38 mmol/L; Albumin 37 g/L; Total Protein 6.1 g/dL; Glucose 5.06 mmol/L.
- Day 1,066 (ECOG 0): Hemoglobin 8.56 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 276 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 9.28 mmol/L; Calcium 2.28 mmol/L; Albumin 41 g/L; Total Protein 6.4 g/dL; Glucose 4.13 mmol/L.
- Day 1,157 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.45 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.25 mg/dL; Immunoglobulin G 5.69 g/L; Immunoglobulin A 1.27 g/L; Immunoglobulin M 0.3 g/L; Hemoglobin 7.94 mmol/L; Leukocytes 6.9 ×10⁹/L; Absolute Neutrophil 4.8 ×10⁹/L; Platelets 227 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 8.93 mmol/L; Calcium 2.35 mmol/L; Albumin 37 g/L; Total Protein 5.5 g/dL; Glucose 5.94 mmol/L.
- Day 1,255 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.57 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.25 mg/dL; Immunoglobulin G 5.8 g/L; Immunoglobulin A 1.16 g/L; Immunoglobulin M 0.05 g/L; Hemoglobin 7.81 mmol/L; Leukocytes 6.9 ×10⁹/L; Absolute Neutrophil 3.8 ×10⁹/L; Platelets 201 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 10 mmol/L; Calcium 2.3 mmol/L; Albumin 38 g/L; Total Protein 5.5 g/dL; Glucose 4.35 mmol/L.
- Day 1,333 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.62 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.26 mg/dL; Immunoglobulin G 6.02 g/L; Immunoglobulin A 1.29 g/L; Immunoglobulin M 0.1 g/L; Hemoglobin 8.43 mmol/L; Leukocytes 5.6 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 177 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.23 mmol/L; Albumin 39 g/L; Total Protein 6.2 g/dL; Glucose 4.46 mmol/L.

Other clinical attributes
- Day -4: Weight: 64 kg; Height: 170 cm.

Family history
- Relative with cancer history: yes; Relationship type: Mother; Relationship primary diagnosis: Colorectal Cancer; Relationship sex at birth: female.
- Relative with cancer history: yes; Relationship type: Father; Relationship sex at birth: male.

Biospecimens (2 samples)
- Sample MMRF_1436_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -4 days.
- Sample MMRF_1436_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -4 days.
